Somatic mutation profile of tumor specimen 0DNMAW from CCDI case PBCBWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 7.3 years (2,672 days).
Specimen 0DNMAW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84eabe2a-3bba-4056-abed-4cf8aaa7b138.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ef4a526-b6b4-4c2e-aa24-bfba129417a7

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Intron 3, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGSF8 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 215/529 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs138031652; called by muse, mutect2, varscan2
- SEPTIN7 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 94/589 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765728361; called by muse, mutect2, varscan2
- SETD2 | c.6229C>T p.R2077* | Nonsense Mutation (SNP) | VAF 325/597 reads (54%) | catalogued as rs1205330893, COSV57434124; called by muse, mutect2, varscan2
- SOX3 | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1304035138; called by muse, mutect2
- TENT5B | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 35/382 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1414188869, COSV100006532; called by muse, mutect2
- ATP11C | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ATP8B1 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 24/912 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BMP2 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 177/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D3 | c.2819+1G>A p.X940_splice | Splice Site (SNP) | VAF 40/336 reads (12%) | called by muse, mutect2, varscan2
- KCNK6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 153/315 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P4HB | c.75C>A p.H25Q | Missense Mutation (SNP) | VAF 80/1057 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2
- SAMD4A | c.471C>G p.S157R | Missense Mutation (SNP) | VAF 44/724 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- SPRY3 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 287/621 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TNNT1 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 156/741 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF324B | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 42/727 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DMD | c.213T>A p.V71= | Silent (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- FAM124B | c.63C>A p.G21= | Silent (SNP) | VAF 229/562 reads (41%) | called by muse, mutect2, varscan2
- GBP3 | c.249G>A p.V83= | Silent (SNP) | VAF 34/544 reads (6%) | called by muse, mutect2
- LYST | c.7410A>G p.L2470= | Silent (SNP) | VAF 23/589 reads (4%) | called by muse, mutect2
- NLRP3 | c.502C>A p.R168= | Silent (SNP) | VAF 33/774 reads (4%) | catalogued as COSV100275560, COSV60223782; called by muse, mutect2
- RGPD4 | c.2928A>G p.A976= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- RTN4RL2 | c.192A>T p.R64= | Silent (SNP) | VAF 93/397 reads (23%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1572C>T p.D524= | Silent (SNP) | VAF 25/422 reads (6%) | catalogued as rs747443468; ClinVar: likely benign; called by muse, mutect2
- C3orf35 | chr3:37417716 G>A | 3'Flank (SNP) | VAF 18/85 reads (21%) | catalogued as rs1231793141; called by muse, mutect2, varscan2
- FARSA | c.1026+25C>T | Intron (SNP) | VAF 34/712 reads (5%) | catalogued as rs1024190533; called by muse, mutect2
- MCM2 | c.2448+56C>T | Intron (SNP) | VAF 28/284 reads (10%) | catalogued as rs915929953, COSV54033167; called by muse, mutect2
- OPRM1 | c.1164+2046G>C | Intron (SNP) | VAF 22/186 reads (12%) | catalogued as rs536957156; called by mutect2, varscan2
- STXBP1 | c.*56C>T | 3'UTR (SNP) | VAF 45/446 reads (10%) | called by muse, mutect2, varscan2
